Somatic mutation profile of tumor specimen ALCH-B1SB-TTP1-A (aliquot ALCH-B1SB-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1SB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.4 years (23,885 days).
Specimen ALCH-B1SB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1271a4f1-d033-41de-b315-69e70628e4ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1SB-NB1-A (Blood Derived Normal), aliquot ALCH-B1SB-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a56d345-d382-42fa-aad8-c4972ee85131

The open-access MAF lists 211 somatic variants for this specimen: 133 protein-altering or splice-affecting, 41 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 41, Intron 17, Nonsense Mutation 11, RNA 11, 3'UTR 5, Splice Site 4, Splice Region 3, Frame Shift Del 3, 5'UTR 3, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/271 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65448688, COSV65455055; called by muse, mutect2, varscan2
- AMPH | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 71/451 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV57760706; called by muse, mutect2, varscan2
- AUTS2 | c.3635del p.P1212Lfs*6 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as COSV61432192; called by mutect2, pindel, varscan2
- BIRC6 | c.5167G>T p.E1723* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as COSV70199361; called by muse, mutect2, varscan2
- CASK | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1361659361; called by muse, mutect2, varscan2
- CCDC168 | c.7162T>A p.L2388M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); catalogued as COSV101468925; called by muse, mutect2, varscan2
- CHKB | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 136/605 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs756445442; called by muse, mutect2, varscan2
- DGKK | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65706890; called by muse, mutect2
- DMD | c.7409C>T p.P2470L | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100627889; called by muse, mutect2, varscan2
- DNAJC11 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 45/523 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as rs199968865; called by muse, mutect2
- DUSP8 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1404237484; called by muse, mutect2, varscan2
- EPS8L1 | c.1847C>T p.P616L (on ENST00000201647 / NM_133180.3; = p.P489L on NM_017729.3) | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1323462017; called by muse, mutect2
- ERBB4 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 22/303 reads (7%) | catalogued as rs201872526; called by muse, mutect2
- FREM3 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV100318899; called by muse, mutect2
- GCNT1 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100946634, COSV65059030; called by muse, varscan2
- GRM1 | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 48/462 reads (10%) | catalogued as COSV51234199, COSV99268500; called by muse, mutect2, varscan2
- HJV | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374050984; called by muse, mutect2, varscan2
- IL1RAPL1 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as COSV100150635; called by muse, mutect2
- IL1RAPL1 | c.277G>T p.G93* | Nonsense Mutation (SNP) | VAF 13/130 reads (10%) | catalogued as COSV56268188, COSV56274403; called by muse, mutect2, varscan2
- KRTAP20-1 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 23/195 reads (12%) | PolyPhen probably damaging (0.985); catalogued as COSV58169231; called by muse, mutect2, varscan2
- MAN2C1 | c.397A>T p.R133W | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV51237286; called by muse, mutect2
- MUC16 | c.15122C>A p.S5041Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1568859857; called by muse, mutect2, varscan2
- MYH2 | c.4033G>A p.D1345N | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs531291725; called by muse, mutect2
- NCKAP5 | c.3934C>G p.L1312V | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs763106243; called by muse, varscan2
- NCKAP5 | c.3791C>A p.P1264Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780666011; called by muse, varscan2
- NDRG4 | c.372+7C>A | Splice Region (SNP) | VAF 16/248 reads (6%) | catalogued as rs750489695; called by muse, mutect2
- NDUFA9 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV56932956; called by muse, mutect2, varscan2
- NTSR2 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV60990943; called by muse, mutect2, varscan2
- OR10G9 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 107/518 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1269012975, COSV66686529; called by muse, mutect2, varscan2
- OR4D11 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 80/445 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1473683395; called by muse, mutect2, varscan2
- ORC1 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV65363446; called by muse, mutect2, varscan2
- PCDHB11 | c.1793A>G p.Q598R | Missense Mutation (SNP) | VAF 47/530 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs1344118174; called by muse, mutect2, varscan2
- RBM28 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778149110, COSV56161898; called by muse, mutect2, varscan2
- SCARB1 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 47/642 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs926860514, COSV104377539; called by muse, mutect2
- SCN3A | c.4434T>C p.F1478= | Splice Region (SNP) | VAF 19/132 reads (14%) | catalogued as COSV51828050; called by muse, mutect2, varscan2
- SRSF4 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100861449; called by muse, mutect2
- TAS2R38 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); catalogued as COSV71885966; called by muse, mutect2, varscan2
- TENM2 | c.5370C>A p.S1790R (on ENST00000518659 / NM_001122679.2; = p.S1551R on NM_001080428.3) | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs769335374, COSV101319216; called by muse, mutect2, varscan2
- TEX55 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 60/552 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV99817586; called by muse, mutect2, varscan2
- THSD7B | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55648336, COSV55742726; called by muse, mutect2, varscan2
- TRIM58 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV63571211; called by muse, mutect2, varscan2
- TRPV6 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs369576441; called by muse, mutect2
- TTC21A | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs762653694, COSV57185265, COSV57186418; called by muse, mutect2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2
- ULK4 | c.1472A>G p.Y491C | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs947769445, COSV100091263; called by muse, mutect2, varscan2
- WARS2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52481474; called by muse, mutect2
- XIRP1 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV61141058; called by muse, mutect2, varscan2
- XIRP2 | c.9533G>T p.R3178I (on ENST00000628543; = p.R3353I on NM_152381.6) | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV54702780; called by muse, mutect2
- ZBTB7A | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV59326557; called by muse, mutect2
- ZEB2 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1158068939; called by muse, mutect2, varscan2
- ZNF695 | c.1270A>T p.T424S | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs371815385; called by muse, mutect2
- ZNF713 | c.96G>T p.E32D (on ENST00000633730 / NM_001366796.2; = p.E45D on NM_182633.3) | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101289510; called by muse, mutect2, varscan2
- AASDH | c.1667G>T p.W556L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ACCS | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.1809G>T p.K603N | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AP1G2 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 28/411 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2
- ARAP1 | c.2888A>T p.Q963L (on ENST00000393609 / NM_001040118.2; = p.Q718L on NM_015242.4) | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX1 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ARMCX3 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ATP8B4 | c.2926del p.A976Pfs*35 | Frame Shift Del (DEL) | VAF 30/250 reads (12%) | called by pindel, varscan2
- BIRC6 | c.5168A>G p.E1723G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C1QTNF7 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCIN | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 66/616 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CETN3 | c.158C>A p.A53E | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- COL13A1 | c.1845+2T>G p.X615_splice (on ENST00000398978 / NM_001130103.2; = p.X543_splice on NM_080798.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- CPS1 | c.1354A>T p.M452L | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSRNP2 | c.708+1del p.X236_splice | Splice Site (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 68/654 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DGKK | c.3500T>A p.L1167Q | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- DIO2 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DLL4 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- DNAH14 | c.1424A>T p.K475M (on ENST00000445597; = p.K456M on NM_001367479.1) | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- DOCK10 | c.1686A>G p.R562= | Splice Region (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- EIF5 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ENPP7 | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 68/467 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- EPB42 | c.1975G>C p.V659L (on ENST00000441366 / NM_001114134.2; = p.V689L on NM_000119.3) | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- ETV3 | c.294_298del p.Y98* | Nonsense Mutation (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel
- F13A1 | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2
- FRMD4B | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSIP2 | c.10000G>A p.V3334I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- FSTL5 | c.1845T>A p.F615L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- GLI3 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPR50 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2
- GTF3C1 | c.3858+1G>C p.X1286_splice | Splice Site (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- HCN1 | c.2170G>C p.A724P | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- HOXC9 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.564); called by muse, mutect2
- HR | c.2367+2T>G p.X789_splice | Splice Site (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- KATNIP | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2
- KCNJ1 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KDM1A | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KIRREL3 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LMBR1L | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- LPA | c.4341G>A p.W1447* | Nonsense Mutation (SNP) | VAF 67/326 reads (21%) | called by muse, mutect2, varscan2
- LRRN2 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 130/476 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEA12 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MAMLD1 | c.1205C>G p.A402G | Missense Mutation (SNP) | VAF 82/637 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MAOA | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MECP2 | c.846G>T p.E282D | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- MEFV | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 136/708 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- METTL26 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC22 | c.4016_4029del p.S1339Wfs*11 | Frame Shift Del (DEL) | VAF 48/391 reads (12%) | called by mutect2, pindel, varscan2
- NETO1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOBOX | c.2032C>A p.L678M | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- NPY1R | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRIP1 | c.1910G>A p.C637Y | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUTM1 | c.2054C>A p.S685* | Nonsense Mutation (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- ODF2 | c.1010A>C p.E337A (on ENST00000434106 / NM_153433.2; = p.E313A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/841 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2
- PAPPA2 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 132/482 reads (27%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHRF1 | c.1823C>T p.P608L (on ENST00000264555 / NM_001286581.2; = p.P607L on NM_020901.4) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLXNB3 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PPFIA4 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PROS1 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- RAG1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF3 | c.1333G>T p.E445* (on ENST00000389212; = p.E403* on NM_006105.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- RELN | c.7655T>C p.L2552P | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNGTT | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- SEMA6A | c.2314C>A p.R772S | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN1 | c.1312A>G p.K438E (on ENST00000356644 / NM_001199933.1; = p.K497E on NM_014454.3) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC22A1 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, varscan2
- SMARCC2 | c.1674G>T p.M558I | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- SOWAHD | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULF1 | c.2113G>C p.A705P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, varscan2
- TEX13C | c.2047C>G p.P683A | Missense Mutation (SNP) | VAF 117/978 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); called by muse, varscan2
- TGFBR2 | c.169A>T p.R57* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- TMEM115 | c.1023_1025del p.I342del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- TOMM40L | c.881A>T p.H294L | Missense Mutation (SNP) | VAF 72/542 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TPK1 | c.336A>G p.I112M | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); called by muse, varscan2
- UPF3B | c.1210G>T p.G404* (on ENST00000276201 / NM_080632.3; = p.G391* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- UPF3B | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- VCAN | c.7262C>A p.P2421Q | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- ZBED1 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ZNF98 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ABCC8 | c.2202A>T p.S734= | Silent (SNP) | VAF 19/200 reads (10%) | catalogued as CD131774; called by muse, mutect2, varscan2
- ALPK1 | c.2178T>A p.S726= | Silent (SNP) | VAF 54/297 reads (18%) | called by muse, mutect2, varscan2
- ALPK2 | c.2208C>T p.D736= | Silent (SNP) | VAF 18/249 reads (7%) | catalogued as rs777001151; called by muse, mutect2
- AMER1 | c.1458C>A p.A486= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- ATP2B3 | c.2421G>A p.V807= | Silent (SNP) | VAF 48/393 reads (12%) | called by muse, mutect2, varscan2
- CACNG4 | c.282C>T p.H94= | Silent (SNP) | VAF 19/312 reads (6%) | catalogued as rs186352782; called by muse, mutect2
- CDH9 | c.1614C>A p.T538= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, varscan2
- CYTH4 | c.1167G>A p.K389= | Silent (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- FLNC | c.6798C>T p.I2266= | Silent (SNP) | VAF 94/382 reads (25%) | catalogued as rs754105222, COSV57950099; called by muse, mutect2, varscan2
- FOLR1 | c.510A>T p.A170= | Silent (SNP) | VAF 104/562 reads (19%) | called by muse, mutect2, varscan2
- FREM3 | c.5439T>C p.D1813= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, varscan2
- GABRA4 | c.519C>A p.P173= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- GLYR1 | c.1317C>T p.I439= | Silent (SNP) | VAF 93/265 reads (35%) | catalogued as COSV100424189; called by muse, mutect2, varscan2
- GPC6 | c.1515G>C p.V505= | Silent (SNP) | VAF 199/1037 reads (19%) | called by muse, mutect2, varscan2
- GPR162 | c.789C>T p.A263= | Silent (SNP) | VAF 108/395 reads (27%) | catalogued as rs1555119729; called by muse, varscan2
- HCFC1 | c.1467G>T p.V489= | Silent (SNP) | VAF 53/502 reads (11%) | catalogued as rs1569546870; called by muse, mutect2, varscan2
- HDC | c.432C>A p.G144= | Silent (SNP) | VAF 57/433 reads (13%) | catalogued as COSV51068448; called by muse, mutect2, varscan2
- LCT | c.3618C>T p.L1206= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1398541471, COSV51559111; called by muse, mutect2, varscan2
- LRRC7 | c.4083T>C p.F1361= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- MAGEC1 | c.405C>T p.F135= | Silent (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- MPEG1 | c.1704C>A p.I568= | Silent (SNP) | VAF 14/430 reads (3%) | catalogued as COSV57089377; called by muse, mutect2
- MUC16 | c.29403A>T p.T9801= | Silent (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- NOBOX | c.1746C>T p.I582= | Silent (SNP) | VAF 57/373 reads (15%) | catalogued as rs1365549881; called by muse, mutect2, varscan2
- OOEP | c.199C>A p.R67= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV64859273; called by muse, mutect2
- OR51C1P | c.240C>A p.T80= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- P2RX5 | c.954C>A p.I318= | Silent (SNP) | VAF 62/330 reads (19%) | called by muse, mutect2, varscan2
- PAK4 | c.1377T>C p.F459= | Silent (SNP) | VAF 51/251 reads (20%) | catalogued as rs772487274; called by muse, mutect2, varscan2
- PCDHB6 | c.1221G>T p.L407= | Silent (SNP) | VAF 59/344 reads (17%) | called by muse, mutect2, varscan2
- PHF3 | c.96G>A p.E32= | Silent (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- PHKA1 | c.186G>T p.R62= | Silent (SNP) | VAF 66/621 reads (11%) | called by muse, mutect2, varscan2
- PROKR2 | c.804C>G p.R268= | Silent (SNP) | VAF 17/444 reads (4%) | catalogued as COSV99450606; called by muse, mutect2
- PRUNE1 | c.1233C>A p.P411= | Silent (SNP) | VAF 142/483 reads (29%) | called by muse, mutect2, varscan2
- RHBDF2 | c.96G>A p.P32= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs759640661, COSV57421172; called by muse, mutect2, varscan2
- RTL5 | c.654G>T p.P218= | Silent (SNP) | VAF 43/394 reads (11%) | called by muse, mutect2, varscan2
- SIT1 | c.72C>A p.G24= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV99425835; called by muse, mutect2, varscan2
- SLIT3 | c.2319C>A p.A773= | Silent (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- TBC1D24 | c.112C>T p.L38= | Silent (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- TCTN2 | c.867G>A p.K289= | Silent (SNP) | VAF 22/306 reads (7%) | called by muse, mutect2
- TLR9 | c.2487C>T p.G829= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as rs201349116; called by muse, mutect2
- XCR1 | c.420C>T p.V140= | Silent (SNP) | VAF 41/306 reads (13%) | called by muse, mutect2, varscan2
- ZDHHC22 | c.351C>T p.C117= | Silent (SNP) | VAF 56/453 reads (12%) | catalogued as rs749809747; called by muse, mutect2, varscan2
- AC012236.1 | n.519G>T | RNA (SNP) | VAF 13/438 reads (3%) | called by muse, mutect2
- AL035696.1 | n.314C>T | RNA (SNP) | VAF 40/279 reads (14%) | called by muse, mutect2, varscan2
- AL136982.4 | n.1100G>T | RNA (SNP) | VAF 208/1227 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.682-393C>T | Intron (SNP) | VAF 23/132 reads (17%) | catalogued as rs782512927; called by muse, mutect2, varscan2
- ASPDH | c.653+31A>C | Intron (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- CCDC74B | c.296-131C>G | Intron (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.7117+576G>T | Intron (SNP) | VAF 65/367 reads (18%) | called by muse, mutect2, varscan2
- CFH | c.2957-29G>A | Intron (SNP) | VAF 51/179 reads (28%) | catalogued as rs56191748; called by muse, mutect2, varscan2
- CSRP1 | c.412-1613T>A | Intron (SNP) | VAF 17/135 reads (13%) | catalogued as rs1445549111; called by muse, mutect2, varscan2
- CYP4V2 | c.605-35G>C | Intron (SNP) | VAF 71/388 reads (18%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 8/96 reads (8%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2
- FLNA | c.4475-41del | Intron (DEL) | VAF 29/226 reads (13%) | called by mutect2, pindel, varscan2
- FOLH1B | n.878C>A | RNA (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- FXYD2 | c.65-95C>G | Intron (SNP) | VAF 14/86 reads (16%) | catalogued as rs1480109995; called by muse, mutect2, varscan2
- GJB1 | c.*25T>A | 3'UTR (SNP) | VAF 43/268 reads (16%) | called by muse, mutect2, varscan2
- GJD4 | c.-6G>T | 5'UTR (SNP) | VAF 69/412 reads (17%) | called by muse, mutect2, varscan2
- GJD4 | c.-5G>T | 5'UTR (SNP) | VAF 68/407 reads (17%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2792G>T | RNA (SNP) | VAF 104/758 reads (14%) | called by muse, mutect2, varscan2
- IL10 | c.*45G>T | 3'UTR (SNP) | VAF 50/347 reads (14%) | catalogued as COSV65594597; called by muse, mutect2, varscan2
- INTS6L | c.1287+1038C>A | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- KIR3DX1 | n.378T>A | RNA (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- LIN9 | c.244+40C>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1457821013; called by muse, mutect2
- LINC02873 | n.323T>A | RNA (SNP) | VAF 32/215 reads (15%) | called by muse, mutect2, varscan2
- LRFN4 | c.*56C>T | 3'UTR (SNP) | VAF 12/383 reads (3%) | catalogued as rs1456103387; called by muse, mutect2
- MIR6511B2 | chr16:15130693 G>T | 3'Flank (SNP) | VAF 113/437 reads (26%) | catalogued as COSV59327375; called by muse, mutect2, varscan2
- MMADHC | c.610-1149C>G | Intron (SNP) | VAF 7/93 reads (8%) | catalogued as rs1159899054; called by muse, mutect2
- NR5A2 | c.1110+8842G>T | Intron (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- OR7D1P | n.725G>T | RNA (SNP) | VAF 49/256 reads (19%) | called by muse, mutect2, varscan2
- OR7E5P | n.661G>C | RNA (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-351G>T | Intron (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- PPP2R2B | c.1052+902C>T | Intron (SNP) | VAF 23/147 reads (16%) | catalogued as rs563632615; called by muse, mutect2, varscan2
- REG1B | c.433+15del | Intron (DEL) | VAF 27/255 reads (11%) | called by mutect2, pindel, varscan2
- SMIM27 | c.*711T>C | 3'UTR (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.512C>T | RNA (SNP) | VAF 74/302 reads (25%) | called by muse, varscan2
- TMEM183B | n.378C>T | RNA (SNP) | VAF 31/424 reads (7%) | catalogued as rs377374014; called by muse, mutect2
- TRBV3-1 | c.-6T>A | 5'UTR (SNP) | VAF 58/293 reads (20%) | called by muse, varscan2
- ZNF275 | c.32-873G>C | Intron (SNP) | VAF 16/231 reads (7%) | catalogued as rs376137626; called by muse, mutect2
